National Lung Screening Trial (NLST) participant 104917 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 66 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 31): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, display field of view 40 cm, reconstruction filter GE, other.
- T1 (day 373): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 70 mA, 41 effective mAs, display field of view 36 cm, reconstruction filter GE, other.
- T2 (day 722): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 70 mA, 41 effective mAs, display field of view 35 cm, reconstruction filter GE Standard / GE Bone.

Abnormalities recorded by the reading radiologist on the CT screens (7 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Emphysema.
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T1 abnormality 1: Emphysema.
- T1 abnormality 2: Benign lung nodule(s) (benign calcification).
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 18 mm, longest perpendicular diameter 9 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 26; new (not pre-existing on earlier images).
- T2 abnormality 2: Emphysema.
- T2 abnormality 3: Benign lung nodule(s) (benign calcification).

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,573.
